Surgical pathology report (de-identified scan), TCGA case TCGA-91-6830, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-6830-01A (Primary Tumor).

[page 1 of 2]
Final Pathologic Diagnosis:

BASED ON THE PERFORMED GROSS AND MICROSCOPIC EXAMINATION:

A. Left hilar lymph node, excision:

Metastatic non-small carcinoma with features consistent with adenocarcinoma.

B. Lymph node, aortic pulmonary window, Level 5, excision:

Metastatic Non-small carcinoma with features consistent with adenocarcinoma.
involving 3 of 3 lymph nodes.

C. Lung, left upper lobe lung, left upper lobectomy:

Adenocarcinoma, moderately differentiated, extensively necrotic.

- Maximal diameter of tumor, 2.8 cm. - Inked margins of resection, free of tumor.

- Bronchial margin, free of tumor.

D. Inferior pulmonary ligament lymph nodes, left side, excision:

Three small lymph nodes with sinus histiocytosis.

No evidence of neoplasia.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

***Electronically Signed ***

Gross Description:

There are four containers, all labeled with the patient's name, " ".

A. Container one is additionally labeled "left hilar lymph node". The specimen is received without fixative and consists of three irregular fragments of pink-tan to black soft tissue measuring in aggregate 2.6 x 1.4 x 1.2 cm. Sectioning reveals that the tissue fragments are lymph node fragments with marked anthracosis. Representative sections of all fragments are submitted in cassette "A".

B. Container two is additionally labeled "aortic pulmonary window level five". The specimen is received without fixative and consists of four irregular fragments of pink-red to black soft tissue measuring in aggregate 1.4 x 1.1 x 0.4 cm. The specimen is entirely submitted in cassette "B".

C. Container three is additionally labeled "left upper lobe lung". The specimen is received without fixative and consists of a left upper lung lobe measuring 20.4 x 9.5 x 3.7 cm. and weighing 165.5 gm. The pleura shows mild anthracosis. There is an umbilication of the pleura on the posterolateral aspect of the lung 7.2 cm. from the apex. This umbilication, which measures 2.2 x 1.5 cm. is inked red. On the medial aspect of the lung, there is a stapled line which traverses the hilus, with a total length of 7.0 cm. This resection margin is inked black. The bronchovascular surgical margins are collected, and the bronchi and vessels are opened beginning at the hilus. No intraluminal lesions are present. The specimen is serially sectioned. There is a mass underneath and abutting the umbilicated pleura, measuring 2.8 x 2.6 x 1.5 cm.

[page 2 of 2]
The mass has a tan to gray, soft cut surface with central anthracosis and well-defined pushing borders. It is distant from the stapled resection margins. The nontumorous lung parenchyma is grossly unremarkable. Four peribronchial lymph nodes are identified, measuring from 0.5 x 0.3 x 0.3 cm. up to 2.0 x 1.3 x 1.2 cm. All lymph nodes show a severely anthracotic cut surface with no focal lesions.

Representative sections are submitted as follows: cassette "C 1" bronchial and vascular surgical margins; cassettes "C 2" peribronchial lymph nodes; cassettes "C 3-5" mass; cassette "C 6" random sections of lung, including stapled resection margin. Small portions of the mass and normal lung parenchyma are also submitted to Tissue Procurement.

D. Container four is additionally labeled "inferior pulmonary ligament lymph node left". The specimen is received without fixative and consists of an irregular fragment of pink-red to black soft tissue measuring 0.9 x 0.7 x 0.3 cm. The specimen is entirely submitted in cassette "D".

Taken: [REDACTED]

Source: NCI Genomic Data Commons file 38ada0d3-f7db-40da-93fe-823456f9517f (TCGA-91-6830.B2952294-4A8A-4C55-BCD0-17ADA4209841.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).